Somatic mutation profile of cancer-model specimen HCM-WCMC-1292-C67-85A (3D Organoid; aliquot HCM-WCMC-1292-C67-85A-01D-A905-36), derived from the primary tumor of HCMI case HCM-WCMC-1292-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3; Age at diagnosis: 60.3 years (22,029 days).
Specimen HCM-WCMC-1292-C67-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff760d06-025e-4c3a-8c02-258d5b506ff0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1292-C67-10A (Blood Derived Normal), aliquot HCM-WCMC-1292-C67-10A-01D-A905-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f5bfff46-96b9-410f-8717-44190a752b72

The open-access MAF lists 391 somatic variants for this specimen: 281 protein-altering or splice-affecting, 95 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 242, Silent 95, Nonsense Mutation 26, Intron 7, Frame Shift Del 5, Splice Region 3, 5'UTR 2, Frame Shift Ins 2, 5'Flank 2, RNA 2, Splice Site 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 309/555 reads (56%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD3 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 125/406 reads (31%) | catalogued as rs387906856, COSV59291372; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 144/307 reads (47%) | catalogued as rs1555526101, COSV52661795, COSV52683537, COSV52718793; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS17 | c.1320C>G p.L440= | Splice Region (SNP) | VAF 58/215 reads (27%) | catalogued as rs1298960675; called by muse, mutect2, varscan2
- ADRA1A | c.1313C>A p.P438H | Missense Mutation (SNP) | VAF 298/465 reads (64%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.121); catalogued as COSV52372424; called by muse, mutect2, varscan2
- AMPD2 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 91/281 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs765794204, COSV56648064; called by muse, mutect2, varscan2
- ARSJ | c.548G>A p.R183K | Missense Mutation (SNP) | VAF 100/248 reads (40%) | SIFT tolerated (0.97); PolyPhen benign (0.023); catalogued as rs369205905; called by muse, mutect2, varscan2
- ATF7IP | c.3797C>G p.S1266C | Missense Mutation (SNP) | VAF 67/326 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV53769148; called by muse, mutect2, varscan2
- ATP12A | c.342dup p.F115Vfs*64 | Frame Shift Ins (INS) | VAF 125/700 reads (18%) | catalogued as rs35191129; called by mutect2, varscan2
- B4GALNT4 | c.2104G>A p.D702N | Missense Mutation (SNP) | VAF 200/777 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1351836232, COSV57322866; called by muse, mutect2, varscan2
- BCAN | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 323/481 reads (67%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.833); catalogued as rs537017904; called by muse, mutect2, varscan2
- BDKRB2 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 213/339 reads (63%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs200131401, COSV60015043; called by muse, mutect2, varscan2
- BNIP1 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 76/366 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571663655, COSV99199362; called by muse, mutect2, varscan2
- BSX | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 168/725 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV58005545; called by muse, mutect2, varscan2
- CCDC33 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 116/384 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.801); catalogued as rs1222079318; called by muse, mutect2, varscan2
- CCKBR | c.1219del p.R407Afs*44 | Frame Shift Del (DEL) | VAF 529/924 reads (57%) | catalogued as COSV58099764; called by mutect2, pindel, varscan2
- CCT5 | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 70/801 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV54724151; called by muse, mutect2
- CLMN | c.1266C>G p.I422M | Missense Mutation (SNP) | VAF 96/325 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as rs1241353858; called by muse, mutect2, varscan2
- CMYA5 | c.8030G>A p.R2677K | Missense Mutation (SNP) | VAF 232/468 reads (50%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs766083938, COSV71405111; called by mutect2, varscan2
- COL2A1 | c.3291G>T p.M1097I | Missense Mutation (SNP) | VAF 23/624 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1328945853; called by muse, mutect2
- COL5A3 | c.3341C>T p.P1114L | Missense Mutation (SNP) | VAF 128/472 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); catalogued as rs750592534, COSV53405245; called by muse, mutect2, varscan2
- CSMD1 | c.3825A>T p.I1275= (on ENST00000520002; = p.I1274= on NM_033225.6) | Splice Region (SNP) | VAF 81/219 reads (37%) | catalogued as COSV100146678; called by muse, mutect2, varscan2
- CYP4B1 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 97/324 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV54721677, COSV54724067; called by muse, mutect2, varscan2
- DHTKD1 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 85/272 reads (31%) | catalogued as rs780313786, COSV53802107, COSV99536270; called by muse, mutect2, varscan2
- DHX37 | c.1942C>T p.R648C | Missense Mutation (SNP) | VAF 243/517 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs201143572, COSV58131874; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2560G>A p.G854S | Missense Mutation (SNP) | VAF 169/839 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761789060, COSV100668569, COSV100668822; called by muse, mutect2, varscan2
- EFCAB6 | c.2866G>T p.V956L | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV53070791; called by muse, mutect2, varscan2
- EFCC1 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 174/739 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1248795951; called by muse, mutect2, varscan2
- ENTPD4 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 75/238 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as rs1329689175, COSV62269242; called by muse, mutect2, varscan2
- F5 | c.5140G>A p.E1714K | Missense Mutation (SNP) | VAF 94/345 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV100888832; called by muse, mutect2, varscan2
- FADD | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 331/477 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV57229323, COSV57229544; called by muse, mutect2, varscan2
- FBXO38 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 341/736 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.033); catalogued as rs548894296, COSV57029894; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGD5 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 152/669 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as rs376698279; called by muse, mutect2, varscan2
- FGGY | c.1343C>G p.S448* | Nonsense Mutation (SNP) | VAF 97/271 reads (36%) | catalogued as rs1288440386; called by muse, mutect2, varscan2
- FZD9 | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 324/494 reads (66%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as COSV60669898; called by muse, mutect2, varscan2
- GAD1 | c.1025A>G p.N342S | Missense Mutation (SNP) | VAF 103/199 reads (52%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs144099065; called by muse, mutect2, varscan2
- GFY | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 160/934 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as rs756665712; called by muse, mutect2, varscan2
- GRIN3A | c.693G>C p.E231D | Missense Mutation (SNP) | VAF 99/277 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.048); catalogued as COSV100701367, COSV62451415; called by muse, mutect2, varscan2
- GUCY1A2 | c.1726G>T p.A576S | Missense Mutation (SNP) | VAF 85/360 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1428098734; called by muse, mutect2, varscan2
- HLA-E | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 143/538 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); catalogued as COSV64927919; called by muse, mutect2, varscan2
- HSPA1A | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 117/430 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65148954; called by muse, mutect2, varscan2
- IL13RA1 | c.1189C>G p.L397V | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.918); catalogued as COSV65424686; called by muse, mutect2, varscan2
- ITGA10 | c.2207G>A p.C736Y | Missense Mutation (SNP) | VAF 171/500 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100994908; called by muse, mutect2, varscan2
- KALRN | c.3517G>C p.E1173Q | Missense Mutation (SNP) | VAF 171/382 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV53757060, COSV53769802; called by muse, mutect2, varscan2
- KCNJ16 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 138/436 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs769285903, COSV99388825; called by muse, mutect2, varscan2
- KCNV1 | c.831C>G p.I277M | Missense Mutation (SNP) | VAF 257/557 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV52088876, COSV99819240; called by muse, mutect2, varscan2
- KDM4B | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 242/485 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50258807; called by muse, mutect2, varscan2
- KIF13A | c.2518G>C p.E840Q | Missense Mutation (SNP) | VAF 206/345 reads (60%) | SIFT tolerated (0.21); PolyPhen benign (0.171); catalogued as rs1302368508, COSV99433877; called by muse, mutect2, varscan2
- KLHDC7A | c.2120C>G p.T707R | Missense Mutation (SNP) | VAF 148/472 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV68770336; called by muse, mutect2, varscan2
- LGR4 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 188/268 reads (70%) | SIFT tolerated (0.2); PolyPhen benign (0.388); catalogued as COSV101004305, COSV99061577; called by muse, mutect2, varscan2
- LMO7 | c.3326A>G p.Y1109C (on ENST00000357063; = p.Y790C on NM_005358.5) | Missense Mutation (SNP) | VAF 163/405 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs533168163; called by muse, mutect2, varscan2
- MARCO | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 100/207 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs779729953; called by muse, mutect2, varscan2
- MECR | c.311G>C p.G104A | Missense Mutation (SNP) | VAF 100/266 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV55286592; called by muse, mutect2, varscan2
- MFNG | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 165/371 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs768635690, COSV52654097, COSV99324834; called by muse, mutect2, varscan2
- MIPEP | c.1147C>G p.L383V | Missense Mutation (SNP) | VAF 191/483 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as COSV66301131; called by muse, mutect2, varscan2
- MLH1 | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 184/377 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV51620875, COSV99212364; called by muse, mutect2, varscan2
- MTMR6 | c.227G>C p.R76T | Missense Mutation (SNP) | VAF 208/562 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.606); catalogued as COSV67808157; called by muse, mutect2, varscan2
- MUC16 | c.37861G>C p.D12621H | Missense Mutation (SNP) | VAF 186/610 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.992); catalogued as COSV67476780; called by muse, mutect2, varscan2
- MYH14 | c.5506C>G p.L1836V | Missense Mutation (SNP) | VAF 484/780 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs1459334407; called by muse, mutect2, varscan2
- NIPAL1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.046); catalogued as rs267600174, COSV55005788; called by muse, mutect2
- NPC1 | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); catalogued as rs1444708311, COSV52575925; called by muse, mutect2, varscan2
- NPY5R | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV58451456; called by muse, mutect2, varscan2
- NWD2 | c.4729C>G p.R1577G | Missense Mutation (SNP) | VAF 138/252 reads (55%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.982); catalogued as COSV58757650; called by muse, mutect2, varscan2
- OPRM1 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 165/514 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs779965433, COSV57677841; called by muse, mutect2, varscan2
- OR8B8 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 127/508 reads (25%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.011); catalogued as rs544744267, COSV100044939, COSV60144617; called by muse, mutect2, varscan2
- OR8G1 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 90/417 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.089); catalogued as COSV58383397; called by muse, mutect2, varscan2
- OSBPL1A | c.2291+1G>T p.X764_splice (on ENST00000319481 / NM_080597.4; = p.X251_splice on NM_018030.4) | Splice Site (SNP) | VAF 59/193 reads (31%) | catalogued as COSV60197576; called by muse, mutect2, varscan2
- PARD6G | c.1078C>G p.L360V | Missense Mutation (SNP) | VAF 186/946 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.732); catalogued as rs927673676, COSV62061010; called by muse, mutect2, varscan2
- PATJ | c.5377G>C p.E1793Q | Missense Mutation (SNP) | VAF 141/225 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); catalogued as COSV64501893; called by muse, mutect2, varscan2
- PCDHB9 | c.1364C>G p.S455C | Missense Mutation (SNP) | VAF 241/876 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); catalogued as COSV53377597; called by muse, mutect2, varscan2
- PCNX3 | c.4705G>A p.V1569M | Missense Mutation (SNP) | VAF 268/364 reads (74%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as rs753711713, COSV63139106; called by muse, mutect2, varscan2
- PER3 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 214/319 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754761909; called by muse, mutect2, varscan2
- PRAMEF18 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 291/865 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs370187466; called by muse, mutect2
- PRSS57 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 328/657 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs780374901, COSV61385534; called by muse, mutect2, varscan2
- QPCT | c.925C>G p.P309A | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753370184; called by muse, varscan2
- R3HCC1L | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776764430; called by muse, varscan2
- RALGAPB | c.1940C>G p.S647C | Missense Mutation (SNP) | VAF 61/238 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53439161; called by muse, mutect2, varscan2
- RBM10 | c.2485G>T p.E829* | Nonsense Mutation (SNP) | VAF 308/308 reads (100%) | catalogued as COSV61311914; called by muse, mutect2, varscan2
- RHPN1 | c.45G>C p.E15D | Missense Mutation (SNP) | VAF 155/600 reads (26%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs751274170; called by muse, mutect2, varscan2
- RIMBP3 | c.4180G>C p.E1394Q | Missense Mutation (SNP) | VAF 235/695 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs1412478461; called by muse, mutect2, varscan2
- RPRD2 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 145/963 reads (15%) | catalogued as COSV100954732; called by muse, mutect2, varscan2
- SALL3 | c.679C>A p.R227S | Missense Mutation (SNP) | VAF 135/654 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs376584783, COSV101610012; called by muse, mutect2, varscan2
- SALL4 | c.2114C>T p.S705F | Missense Mutation (SNP) | VAF 130/442 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs370485562, COSV53851012; called by muse, mutect2, varscan2
- SASH3 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 402/402 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1000983863; called by muse, mutect2, varscan2
- SDR16C5 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 50/215 reads (23%) | catalogued as COSV100374090, COSV58125587; called by muse, mutect2, varscan2
- SERPINB7 | c.672G>T p.M224I | Missense Mutation (SNP) | VAF 92/344 reads (27%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.977); catalogued as rs760483607, COSV60532958; called by mutect2, varscan2
- SIPA1L3 | c.2126G>A p.R709K | Missense Mutation (SNP) | VAF 90/594 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.055); catalogued as rs759600416; called by muse, mutect2, varscan2
- SLC26A5 | c.512G>C p.R171T | Missense Mutation (SNP) | VAF 102/352 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1216316708, COSV59701945, COSV59704629; called by muse, mutect2, varscan2
- SLC27A1 | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 254/525 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.047); catalogued as rs1424743095; called by muse, mutect2, varscan2
- SLC2A2 | c.977C>G p.S326* | Nonsense Mutation (SNP) | VAF 171/439 reads (39%) | catalogued as CP025177, COSV58588437; called by muse, mutect2, varscan2
- SLC38A2 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 64/383 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs939907883; called by muse, mutect2, varscan2
- SLC9A5 | c.2197C>T p.L733F | Missense Mutation (SNP) | VAF 103/216 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs530527126, COSV100237457; called by muse, varscan2
- SPINT1 | c.1096G>T p.E366* (on ENST00000344051 / NM_181642.3; = p.E350* on NM_003710.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 111/299 reads (37%) | catalogued as COSV59802955; called by muse, mutect2, varscan2
- STAM2 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 66/121 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV55730583; called by muse, mutect2, varscan2
- STMN4 | c.161A>T p.E54V (on ENST00000265770 / NM_001283054.2; = p.E81V on NM_030795.4) | Missense Mutation (SNP) | VAF 147/409 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56110473; called by muse, mutect2, varscan2
- SUPV3L1 | c.1219C>G p.Q407E | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.789); catalogued as rs1242228004; called by muse, mutect2, varscan2
- SYNE2 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 106/347 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100647077; called by muse, mutect2, varscan2
- TBC1D31 | c.864G>T p.M288I | Missense Mutation (SNP) | VAF 141/259 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as COSV54864641; called by muse, mutect2, varscan2
- TBCC | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 124/482 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs1375886421; called by muse, mutect2, varscan2
- TDRD6 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 178/519 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as rs1235146293, COSV60174261; called by muse, mutect2, varscan2
- TENM4 | c.1787C>G p.S596C | Missense Mutation (SNP) | VAF 227/308 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as rs1042781930; called by muse, mutect2, varscan2
- TLX1 | c.580C>G p.Q194E | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64622350; called by muse, mutect2, varscan2
- TMEM176A | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 78/294 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.412); catalogued as rs746353587; called by muse, mutect2, varscan2
- TMEM179B | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 270/546 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); catalogued as COSV53670471; called by muse, mutect2, varscan2
- TMEM272 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 98/277 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.043); catalogued as rs750119800; called by muse, varscan2
- TSHZ3 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 240/484 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.659); catalogued as rs200415244; called by muse, mutect2, varscan2
- WDR11 | c.791A>G p.Y264C | Missense Mutation (SNP) | VAF 104/209 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763258664; called by muse, mutect2, varscan2
- WDR74 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 87/473 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs200010672; called by muse, mutect2, varscan2
- ZMYM2 | c.2596C>T p.H866Y | Missense Mutation (SNP) | VAF 152/402 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67037169; called by muse, mutect2, varscan2
- ZNF107 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 192/333 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100788409; called by muse, mutect2, varscan2
- ZNF230 | c.1167G>C p.E389D | Missense Mutation (SNP) | VAF 124/712 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs1254451217; called by muse, mutect2, varscan2
- ZNF536 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 174/823 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs766395032, COSV62821220; called by muse, mutect2, varscan2
- ZNF681 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV101267592; called by muse, mutect2, varscan2
- ABCA7 | c.1076G>C p.R359T | Missense Mutation (SNP) | VAF 106/453 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ACACA | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACAN | c.6670del p.Q2224Sfs*11 | Frame Shift Del (DEL) | VAF 122/444 reads (27%) | called by mutect2, pindel, varscan2
- ACTB | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 81/438 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRE2 | c.2312del p.G771Vfs*29 | Frame Shift Del (DEL) | VAF 102/494 reads (21%) | called by mutect2, pindel, varscan2
- ADGRG4 | c.1632G>T p.M544I | Missense Mutation (SNP) | VAF 157/309 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRV1 | c.7579C>T p.L2527F | Missense Mutation (SNP) | VAF 115/485 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGO4 | c.685G>C p.D229H | Missense Mutation (SNP) | VAF 126/330 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- AHNAK | c.12065C>T p.S4022F | Missense Mutation (SNP) | VAF 119/524 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ANKRD36B | c.1794G>C p.Q598H | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ARHGEF19 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 244/374 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGEF28 | c.1747G>T p.E583* | Nonsense Mutation (SNP) | VAF 56/203 reads (28%) | called by muse, mutect2, varscan2
- ASB18 | c.851C>A p.A284E | Missense Mutation (SNP) | VAF 160/161 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ASCC2 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 149/272 reads (55%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- ASXL1 | c.1738_1756delinsT p.K580_K586delins* | Nonsense Mutation (DEL) | VAF 380/596 reads (64%) | called by pindel, varscan2*
- B3GNT5 | c.968A>G p.H323R | Missense Mutation (SNP) | VAF 195/541 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BPTF | c.8308G>C p.E2770Q | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- BRCA2 | c.6967C>T p.H2323Y | Missense Mutation (SNP) | VAF 56/360 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- C3 | c.1660G>T p.D554Y | Missense Mutation (SNP) | VAF 106/530 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CACNA1E | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 96/204 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC168 | c.20603G>C p.R6868T | Missense Mutation (SNP) | VAF 127/572 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- CCDC18 | c.4111G>A p.E1371K | Missense Mutation (SNP) | VAF 96/297 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCIN | c.376A>G p.K126E | Missense Mutation (SNP) | VAF 120/341 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- CFAP54 | c.9038C>G p.S3013* | Nonsense Mutation (SNP) | VAF 77/409 reads (19%) | called by muse, mutect2, varscan2
- CHD1 | c.2503G>A p.D835N | Missense Mutation (SNP) | VAF 103/240 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRNA6 | c.1381A>T p.M461L | Missense Mutation (SNP) | VAF 60/272 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- COBL | c.3285C>G p.F1095L | Missense Mutation (SNP) | VAF 139/702 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL18A1 | c.3044C>T p.P1015L (on ENST00000359759 / NM_130444.3; = p.P780L on NM_030582.4) | Missense Mutation (SNP) | VAF 266/407 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- COL22A1 | c.3104C>T p.S1035F | Missense Mutation (SNP) | VAF 101/457 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CSMD2 | c.4489G>C p.D1497H | Missense Mutation (SNP) | VAF 81/271 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCC | c.1294C>A p.P432T | Missense Mutation (SNP) | VAF 101/325 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMXL2 | c.4046C>T p.P1349L | Missense Mutation (SNP) | VAF 193/300 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOCK2 | c.4845G>T p.K1615N | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- DOCK2 | c.4846G>T p.E1616* | Nonsense Mutation (SNP) | VAF 56/278 reads (20%) | called by mutect2, varscan2
- DST | c.15711G>A p.M5237I (on ENST00000361203 / NM_001374722.1; = p.M2825I on NM_015548.5) | Missense Mutation (SNP) | VAF 330/453 reads (73%) | SIFT tolerated (0.21); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DZIP3 | c.3478C>T p.L1160F | Missense Mutation (SNP) | VAF 198/413 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 152/283 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- EIF4A2 | c.1146G>C p.K382N | Missense Mutation (SNP) | VAF 207/597 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ELF3 | c.171_174dup p.W59Qfs*34 | Frame Shift Ins (INS) | VAF 57/142 reads (40%) | called by mutect2, pindel, varscan2
- EP300 | c.2531A>G p.H844R | Missense Mutation (SNP) | VAF 129/262 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- EPHB1 | c.740T>C p.M247T | Missense Mutation (SNP) | VAF 342/669 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- EXOC3L4 | c.1768G>C p.E590Q | Missense Mutation (SNP) | VAF 330/481 reads (69%) | SIFT tolerated (0.11); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- FAM170B | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 153/340 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- FANCM | c.3139C>A p.Q1047K | Missense Mutation (SNP) | VAF 134/198 reads (68%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FBLN2 | c.353C>A p.P118Q | Missense Mutation (SNP) | VAF 288/658 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- FBXW2 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 74/266 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCRL4 | c.755G>A p.W252* | Nonsense Mutation (SNP) | VAF 150/454 reads (33%) | called by muse, mutect2, varscan2
- FER | c.1047-9_1052del p.X349_splice | Splice Site (DEL) | VAF 56/271 reads (21%) | called by mutect2, pindel, varscan2
- FILIP1 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 92/367 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRMPD1 | c.3566C>A p.P1189Q | Missense Mutation (SNP) | VAF 229/338 reads (68%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- GET3 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 209/466 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- GLIS2 | c.888G>C p.K296N | Missense Mutation (SNP) | VAF 206/692 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GLRX2 | c.227C>G p.S76C (on ENST00000367439 / NM_197962.3; = p.S77C on NM_016066.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- GLT1D1 | c.347C>A p.S116* | Nonsense Mutation (SNP) | VAF 77/340 reads (23%) | called by mutect2, varscan2
- GNPTAB | c.1081G>C p.D361H | Missense Mutation (SNP) | VAF 100/458 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GOLGA4 | c.2616A>T p.K872N | Missense Mutation (SNP) | VAF 22/487 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- GPRASP1 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 158/296 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GRB10 | c.1336G>A p.E446K (on ENST00000398812; = p.E400K on NM_001001549.3) | Missense Mutation (SNP) | VAF 115/564 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- GRM6 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 74/293 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- HIVEP1 | c.844C>G p.H282D | Missense Mutation (SNP) | VAF 93/323 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- HIVEP2 | c.5261G>A p.R1754K | Missense Mutation (SNP) | VAF 144/234 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- HMGCLL1 | c.161C>G p.S54* | Nonsense Mutation (SNP) | VAF 134/385 reads (35%) | called by muse, mutect2, varscan2
- IARS1 | c.1869C>T p.L623= | Splice Region (SNP) | VAF 71/283 reads (25%) | called by muse, mutect2, varscan2
- IFNK | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 87/267 reads (33%) | called by muse, mutect2, varscan2
- IFNK | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 100/304 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- IGF2R | c.2021C>G p.P674R | Missense Mutation (SNP) | VAF 105/383 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IL1RAP | c.841T>A p.W281R | Missense Mutation (SNP) | VAF 221/504 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IQANK1 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 228/454 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ITPRID1 | c.582G>C p.E194D | Missense Mutation (SNP) | VAF 83/422 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KAT5 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 96/478 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KCNH3 | c.3064G>C p.E1022Q | Missense Mutation (SNP) | VAF 212/758 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- KCNK12 | c.418G>A p.V140M | Missense Mutation (SNP) | VAF 232/370 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- KCNMA1 | c.3284G>T p.R1095M (on ENST00000286628 / NM_001161352.2; = p.R1037M on NM_002247.4) | Missense Mutation (SNP) | VAF 144/295 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM2A | c.107G>C p.R36T | Missense Mutation (SNP) | VAF 332/474 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KIAA0232 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 37/270 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF20B | c.2209G>A p.E737K (on ENST00000371728 / NM_001284259.2; = p.E697K on NM_016195.4) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIF20B | c.2210A>T p.E737V (on ENST00000371728 / NM_001284259.2; = p.E697V on NM_016195.4) | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- KLF10 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 84/341 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- LTBP1 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 97/320 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MAGEA1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- MAN2B1 | c.1336C>T p.H446Y | Missense Mutation (SNP) | VAF 144/570 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MDGA2 | c.2144A>T p.N715I (on ENST00000399232 / NM_001113498.2; = p.N417I on NM_182830.4) | Missense Mutation (SNP) | VAF 184/288 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- MLLT6 | c.1500T>A p.S500R | Missense Mutation (SNP) | VAF 261/761 reads (34%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- MOB1A | c.26C>G p.S9C | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPV17L | c.191A>T p.Y64F | Missense Mutation (SNP) | VAF 213/693 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- MRPS15 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.14371G>C p.D4791H | Missense Mutation (SNP) | VAF 231/482 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- MYEOV | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 570/770 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- MYH8 | c.1700A>G p.Q567R | Missense Mutation (SNP) | VAF 138/282 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- NBEA | c.3043G>C p.E1015Q | Missense Mutation (SNP) | VAF 131/247 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- NBEAL2 | c.5017G>C p.D1673H | Missense Mutation (SNP) | VAF 136/593 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- NCAM2 | c.613del p.V205Lfs*24 | Frame Shift Del (DEL) | VAF 107/240 reads (45%) | called by pindel, varscan2
- NDE1 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 159/481 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- NPIPB5 | c.2113C>T p.Q705* | Nonsense Mutation (SNP) | VAF 76/1072 reads (7%) | called by muse, varscan2
- NSG2 | c.282G>C p.M94I | Missense Mutation (SNP) | VAF 85/388 reads (22%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2, varscan2
- NUPR2 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 48/778 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR14A2 | c.734T>A p.V245D | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2M3 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 86/178 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARP8 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 63/220 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PCDH8 | c.794T>A p.L265H | Missense Mutation (SNP) | VAF 437/1117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHB3 | c.1279G>T p.G427W | Missense Mutation (SNP) | VAF 439/546 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB1 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 345/516 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PDCD5 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 131/715 reads (18%) | called by muse, mutect2, varscan2
- PDGFD | c.221C>G p.P74R | Missense Mutation (SNP) | VAF 118/567 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEX6 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 195/558 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PIEZO1 | c.5331G>T p.E1777D | Missense Mutation (SNP) | VAF 271/272 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PIEZO1 | c.4285G>A p.E1429K | Missense Mutation (SNP) | VAF 223/223 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- PLEKHH2 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 43/126 reads (34%) | called by muse, mutect2, varscan2
- PPP4R3C | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 83/160 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRDM12 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, varscan2
- PRPF31 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 121/291 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSG8 | c.685_686del p.D229Pfs*26 | Frame Shift Del (DEL) | VAF 85/701 reads (12%) | called by mutect2, pindel, varscan2
- PSTK | c.252G>C p.L84F | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTF1A | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 157/528 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTGFRN | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 145/421 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- PTPRG | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 122/293 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PXDN | c.2059C>T p.Q687* | Nonsense Mutation (SNP) | VAF 115/345 reads (33%) | called by muse, mutect2, varscan2
- PYGB | c.1037C>G p.S346C | Missense Mutation (SNP) | VAF 140/386 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RB1 | c.1656_1664del p.C553_H555del | In Frame Del (DEL) | VAF 93/101 reads (92%) | called by mutect2, pindel, varscan2
- RBM25 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- REXO1 | c.11C>A p.S4Y | Missense Mutation (SNP) | VAF 148/322 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- RNF146 | c.883G>A p.D295N (on ENST00000368314 / NM_001242850.2; = p.D294N on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/301 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPP40 | c.608A>G p.Q203R | Missense Mutation (SNP) | VAF 232/332 reads (70%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPS6KA6 | c.1683C>G p.I561M | Missense Mutation (SNP) | VAF 95/209 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- RSPO2 | c.568A>G p.I190V | Missense Mutation (SNP) | VAF 212/423 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- RYR2 | c.11533C>G p.L3845V | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SBF2 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 203/304 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC1A4 | c.411C>G p.F137L | Missense Mutation (SNP) | VAF 328/494 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SLC30A7 | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 129/200 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SLC39A6 | c.2098G>T p.V700F | Missense Mutation (SNP) | VAF 86/280 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC44A4 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 128/392 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLCO1B1 | c.520G>C p.V174L | Missense Mutation (SNP) | VAF 157/307 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SORCS2 | c.3358G>T p.E1120* | Nonsense Mutation (SNP) | VAF 42/295 reads (14%) | called by muse, mutect2, varscan2
- SOS1 | c.3809G>C p.R1270T | Missense Mutation (SNP) | VAF 126/413 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SPATA31A3 | c.2531C>T p.S844L | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by mutect2, varscan2
- SPG11 | c.2779C>T p.Q927* | Nonsense Mutation (SNP) | VAF 104/317 reads (33%) | called by muse, mutect2, varscan2
- SUDS3 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 113/415 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- TASOR | c.4736C>G p.S1579C (on ENST00000355628 / NM_001365636.2; = p.S1203C on NM_015224.3) | Missense Mutation (SNP) | VAF 107/432 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- TLR1 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.089); called by muse, mutect2
- TLX1 | c.306C>G p.N102K | Missense Mutation (SNP) | VAF 169/404 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TOPBP1 | c.2359C>T p.Q787* | Nonsense Mutation (SNP) | VAF 308/618 reads (50%) | called by muse, mutect2, varscan2
- TPX2 | c.1121C>G p.T374S | Missense Mutation (SNP) | VAF 938/1271 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRAV21 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- TRIP10 | c.484A>G p.I162V | Missense Mutation (SNP) | VAF 223/463 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TSNARE1 | c.1061G>C p.G354A | Missense Mutation (SNP) | VAF 120/466 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTC14 | c.2026G>C p.E676Q | Missense Mutation (SNP) | VAF 96/479 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- TTN | c.20171C>A p.A6724E (on ENST00000591111; = p.A5797E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/156 reads (5%) | PolyPhen benign (0.026); called by muse, mutect2
- TWSG1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 126/407 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- UGT1A7 | c.292T>A p.W98R | Missense Mutation (SNP) | VAF 205/205 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- USP25 | c.1570C>G p.Q524E | Missense Mutation (SNP) | VAF 125/414 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- UTRN | c.3593C>T p.S1198F | Missense Mutation (SNP) | VAF 236/350 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- VCAN | c.3526G>C p.E1176Q | Missense Mutation (SNP) | VAF 132/470 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- YEATS4 | c.113G>C p.R38T | Missense Mutation (SNP) | VAF 54/285 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- YIPF7 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZC3H7B | c.1438G>A p.G480S | Missense Mutation (SNP) | VAF 97/226 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZC3H7B | c.1439G>T p.G480V | Missense Mutation (SNP) | VAF 97/226 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZCWPW2 | c.221C>G p.S74C | Missense Mutation (SNP) | VAF 88/367 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ZNF106 | c.1065G>C p.Q355H | Missense Mutation (SNP) | VAF 131/381 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- ZNF136 | c.629G>C p.R210T | Missense Mutation (SNP) | VAF 114/517 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF226 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 130/832 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ZNF543 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 10/272 reads (4%) | called by muse, mutect2
- ZNF556 | c.684G>C p.E228D | Missense Mutation (SNP) | VAF 131/520 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF585A | c.1641G>C p.E547D (on ENST00000292841 / NM_001288800.2; = p.E492D on NM_152655.3) | Missense Mutation (SNP) | VAF 101/702 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF587 | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 137/490 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, varscan2
- ZNF623 | c.1156C>A p.L386M | Missense Mutation (SNP) | VAF 286/592 reads (48%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF777 | c.1202C>G p.S401* | Nonsense Mutation (SNP) | VAF 157/483 reads (33%) | called by muse, mutect2, varscan2
- ZNF792 | c.1886G>C p.G629A | Missense Mutation (SNP) | VAF 318/512 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- ZNF845 | c.2140A>G p.T714A | Missense Mutation (SNP) | VAF 102/183 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- ADCY9 | c.18C>T p.H6= | Silent (SNP) | VAF 80/279 reads (29%) | called by muse, mutect2, varscan2
- ADGRF3 | c.2091C>T p.F697= (on ENST00000311519 / NM_001145168.1; = p.F498= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 161/463 reads (35%) | catalogued as rs865936813, COSV61052318; called by muse, mutect2, varscan2
- AKAP7 | c.531G>A p.Q177= | Silent (SNP) | VAF 190/299 reads (64%) | called by muse, mutect2, varscan2
- ANKLE1 | c.450G>A p.L150= (on ENST00000394458; = p.L96= on NM_152363.6) | Silent (SNP) | VAF 114/575 reads (20%) | called by muse, mutect2, varscan2
- AP5Z1 | c.1236G>A p.Q412= | Silent (SNP) | VAF 405/698 reads (58%) | catalogued as rs546607746; called by muse, mutect2, varscan2
- APBB1 | c.1941A>C p.S647= | Silent (SNP) | VAF 224/448 reads (50%) | called by muse, mutect2, varscan2
- ATP13A5 | c.3453C>T p.F1151= | Silent (SNP) | VAF 114/633 reads (18%) | called by muse, mutect2, varscan2
- ATP7B | c.3582C>T p.I1194= | Silent (SNP) | VAF 137/639 reads (21%) | catalogued as rs761183334; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AVPR1B | c.628C>T p.L210= | Silent (SNP) | VAF 115/279 reads (41%) | called by muse, mutect2, varscan2
- BFSP2 | c.91C>A p.R31= | Silent (SNP) | VAF 371/780 reads (48%) | catalogued as COSV56590543; called by muse, mutect2, varscan2
- BTBD6 | c.936C>T p.F312= | Silent (SNP) | VAF 285/431 reads (66%) | catalogued as COSV59273453; called by muse, mutect2, varscan2
- C4orf17 | c.366C>T p.F122= | Silent (SNP) | VAF 46/114 reads (40%) | called by muse, mutect2, varscan2
- CCDC114 | c.678C>T p.F226= | Silent (SNP) | VAF 132/877 reads (15%) | catalogued as rs867613985; called by muse, varscan2
- CDCP1 | c.375C>T p.F125= | Silent (SNP) | VAF 119/484 reads (25%) | catalogued as rs865805245; called by muse, mutect2, varscan2
- CFAP74 | c.195G>A p.K65= | Silent (SNP) | VAF 105/296 reads (35%) | catalogued as COSV54568063; called by muse, mutect2, varscan2
- CHAF1A | c.1371C>T p.A457= | Silent (SNP) | VAF 192/438 reads (44%) | catalogued as rs139171554; called by muse, mutect2, varscan2
- CHAMP1 | c.1665G>A p.R555= | Silent (SNP) | VAF 159/695 reads (23%) | called by muse, mutect2, varscan2
- CHST8 | c.897C>G p.A299= | Silent (SNP) | VAF 373/1083 reads (34%) | called by muse, mutect2, varscan2
- CLDN6 | c.25C>T p.L9= | Silent (SNP) | VAF 108/341 reads (32%) | catalogued as rs760716801; called by muse, mutect2, varscan2
- CROT | c.1677A>G p.V559= | Silent (SNP) | VAF 77/278 reads (28%) | catalogued as COSV100519401; called by muse, mutect2, varscan2
- CTNNA1 | c.846C>G p.L282= | Silent (SNP) | VAF 74/297 reads (25%) | catalogued as rs1439421661; called by muse, mutect2, varscan2
- DHCR7 | c.1083C>T p.F361= | Silent (SNP) | VAF 331/631 reads (52%) | catalogued as rs780088227, CM143877; called by muse, mutect2, varscan2
- DISC1 | c.2361G>A p.K787= | Silent (SNP) | VAF 111/235 reads (47%) | catalogued as rs1284428560; called by muse, mutect2, varscan2
- DNAH11 | c.8646C>T p.T2882= | Silent (SNP) | VAF 284/457 reads (62%) | catalogued as rs1464421155, COSV60956366; called by muse, mutect2, varscan2
- DTX1 | c.819C>T p.P273= | Silent (SNP) | VAF 84/180 reads (47%) | called by muse, mutect2, varscan2
- DYNC2H1 | c.1569C>G p.L523= | Silent (SNP) | VAF 107/425 reads (25%) | called by muse, mutect2, varscan2
- ELMO3 | c.600G>C p.L200= (on ENST00000652269; = p.L147= on NM_024712.5) | Silent (SNP) | VAF 149/268 reads (56%) | called by muse, mutect2, varscan2
- FBXL12 | c.675C>T p.R225= | Silent (SNP) | VAF 175/697 reads (25%) | called by muse, mutect2, varscan2
- FBXL7 | c.1386G>A p.Q462= | Silent (SNP) | VAF 132/1107 reads (12%) | catalogued as COSV100309102; called by muse, mutect2, varscan2
- FCGRT | c.273G>C p.L91= | Silent (SNP) | VAF 104/763 reads (14%) | called by muse, mutect2, varscan2
- FJX1 | c.447C>T p.R149= | Silent (SNP) | VAF 209/802 reads (26%) | catalogued as rs1407427913; called by muse, mutect2, varscan2
- GBP3 | c.1578G>A p.V526= | Silent (SNP) | VAF 205/327 reads (63%) | catalogued as COSV52520009; called by muse, mutect2, varscan2
- GMEB1 | c.424C>T p.L142= | Silent (SNP) | VAF 94/262 reads (36%) | called by muse, mutect2, varscan2
- GPR152 | c.693C>A p.A231= | Silent (SNP) | VAF 193/760 reads (25%) | called by muse, mutect2, varscan2
- GRIN3B | c.2037G>A p.G679= | Silent (SNP) | VAF 76/384 reads (20%) | catalogued as rs749745750; called by muse, mutect2, varscan2
- HBS1L | c.1110T>C p.D370= | Silent (SNP) | VAF 105/329 reads (32%) | called by muse, mutect2, varscan2
- HCRTR1 | c.900G>C p.L300= | Silent (SNP) | VAF 194/521 reads (37%) | called by muse, mutect2
- HHIPL1 | c.519C>T p.H173= | Silent (SNP) | VAF 150/467 reads (32%) | catalogued as rs372014488; called by muse, mutect2, varscan2
- HHIPL1 | c.1662C>T p.F554= | Silent (SNP) | VAF 92/261 reads (35%) | catalogued as rs1200224720, COSV100415216; called by muse, mutect2, varscan2
- HOXB3 | c.228G>A p.P76= | Silent (SNP) | VAF 420/655 reads (64%) | catalogued as rs149877846; called by muse, mutect2, varscan2
- HS6ST2 | c.261C>T p.F87= | Silent (SNP) | VAF 456/456 reads (100%) | catalogued as COSV63711594, COSV63717164; called by muse, mutect2, varscan2
- ITGA3 | c.3024G>T p.L1008= | Silent (SNP) | VAF 104/341 reads (30%) | called by muse, varscan2
- KCTD16 | c.318G>A p.L106= | Silent (SNP) | VAF 110/440 reads (25%) | called by muse, mutect2, varscan2
- KIF13A | c.3105G>A p.V1035= | Silent (SNP) | VAF 176/266 reads (66%) | catalogued as COSV52458855; called by muse, mutect2, varscan2
- KNDC1 | c.4170C>A p.A1390= | Silent (SNP) | VAF 102/321 reads (32%) | catalogued as COSV100466423; called by muse, mutect2, varscan2
- KNL1 | c.231G>A p.V77= | Silent (SNP) | VAF 13/279 reads (5%) | catalogued as COSV61150520; called by muse, mutect2
- LARP6 | c.699C>G p.L233= | Silent (SNP) | VAF 136/399 reads (34%) | called by muse, mutect2, varscan2
- LCAT | c.1092C>G p.L364= | Silent (SNP) | VAF 134/309 reads (43%) | called by muse, mutect2, varscan2
- MBOAT7 | c.267C>T p.L89= | Silent (SNP) | VAF 341/341 reads (100%) | called by muse, mutect2, varscan2
- NBPF11 | c.213G>A p.L71= | Silent (SNP) | VAF 69/889 reads (8%) | called by muse, mutect2
- NF2 | c.1293G>A p.L431= | Silent (SNP) | VAF 140/279 reads (50%) | catalogued as rs1340711783, COSV104404751; ClinVar: likely benign; called by muse, mutect2, varscan2
- PDZD8 | c.33C>A p.A11= | Silent (SNP) | VAF 97/210 reads (46%) | catalogued as rs966366124; called by muse, mutect2, varscan2
- PKMYT1 | c.735C>T p.G245= | Silent (SNP) | VAF 200/607 reads (33%) | catalogued as rs752679639, COSV99233898; called by muse, mutect2, varscan2
- PLIN4 | c.3195G>A p.Q1065= (on ENST00000301286; = p.Q1080= on NM_001367868.2) | Silent (SNP) | VAF 169/659 reads (26%) | called by muse, mutect2, varscan2
- POSTN | c.1191G>A p.L397= | Silent (SNP) | VAF 125/267 reads (47%) | catalogued as rs1326393116; called by muse, mutect2, varscan2
- POTEF | c.2088G>A p.L696= | Silent (SNP) | VAF 148/360 reads (41%) | called by muse, mutect2, varscan2
- PRAMEF11 | c.582C>T p.F194= | Silent (SNP) | VAF 196/648 reads (30%) | catalogued as COSV70820028; called by muse, mutect2, varscan2
- PREX2 | c.2181C>T p.V727= | Silent (SNP) | VAF 108/414 reads (26%) | called by muse, mutect2, varscan2
- PRKRA | c.372G>A p.Q124= | Silent (SNP) | VAF 80/176 reads (45%) | catalogued as COSV100359655; called by muse, mutect2, varscan2
- RAN | c.81G>A p.V27= | Silent (SNP) | VAF 68/312 reads (22%) | called by muse, mutect2, varscan2
- RBBP7 | c.1023G>C p.L341= | Silent (SNP) | VAF 109/223 reads (49%) | called by muse, mutect2, varscan2
- RHAG | c.1026C>T p.G342= | Silent (SNP) | VAF 170/294 reads (58%) | catalogued as COSV57704621; called by muse, mutect2, varscan2
- RIMBP2 | c.192C>T p.H64= | Silent (SNP) | VAF 280/618 reads (45%) | catalogued as rs372938466; called by muse, mutect2
- RPL18 | c.294G>A p.L98= | Silent (SNP) | VAF 115/601 reads (19%) | called by muse, mutect2, varscan2
- RSF1 | c.4002A>G p.Q1334= | Silent (SNP) | VAF 420/552 reads (76%) | catalogued as rs1438559168; called by muse, mutect2, varscan2
- RSPH10B | c.2613G>A p.*871= | Silent (SNP) | VAF 18/133 reads (14%) | called by mutect2, varscan2
- RTL1 | c.2283C>A p.V761= | Silent (SNP) | VAF 264/401 reads (66%) | called by muse, mutect2, varscan2
- SALL3 | c.678C>A p.I226= | Silent (SNP) | VAF 134/661 reads (20%) | called by muse, mutect2, varscan2
- SCAP | c.2244G>A p.R748= | Silent (SNP) | VAF 388/859 reads (45%) | called by muse, mutect2, varscan2
- SCRT2 | c.831C>T p.F277= | Silent (SNP) | VAF 188/369 reads (51%) | catalogued as rs1221558957; called by muse, mutect2, varscan2
- SHANK2 | c.3315A>G p.T1105= | Silent (SNP) | VAF 185/717 reads (26%) | called by muse, mutect2, varscan2
- SLC4A8 | c.216G>C p.R72= | Silent (SNP) | VAF 166/756 reads (22%) | called by muse, mutect2, varscan2
- SLIT1 | c.1875C>T p.I625= | Silent (SNP) | VAF 114/252 reads (45%) | catalogued as COSV56598348; called by muse, mutect2, varscan2
- SNX4 | c.594G>A p.L198= | Silent (SNP) | VAF 49/265 reads (18%) | catalogued as COSV52536395; called by muse, mutect2, varscan2
- SP1 | c.1602C>T p.L534= (on ENST00000327443 / NM_138473.3; = p.L527= on NM_003109.1) | Silent (SNP) | VAF 134/495 reads (27%) | catalogued as COSV100540896; called by muse, mutect2, varscan2
- SPATA24 | c.15C>G p.L5= | Silent (SNP) | VAF 64/331 reads (19%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.51C>T p.F17= | Silent (SNP) | VAF 110/338 reads (33%) | catalogued as rs749318938, COSV100867738, COSV64532974; called by muse, varscan2
- TACC2 | c.7992C>T p.P2664= (on ENST00000334433; = p.P742= on NM_006997.4) | Silent (SNP) | VAF 105/246 reads (43%) | catalogued as rs762996567; called by muse, mutect2, varscan2
- TDRD6 | c.6072G>A p.L2024= | Silent (SNP) | VAF 87/261 reads (33%) | catalogued as COSV60178418; called by muse, mutect2, varscan2
- TELO2 | c.2496C>G p.L832= | Silent (SNP) | VAF 107/336 reads (32%) | called by muse, mutect2
- TKTL2 | c.387A>T p.G129= | Silent (SNP) | VAF 109/233 reads (47%) | called by muse, mutect2, varscan2
- TMEM267 | c.378G>A p.L126= | Silent (SNP) | VAF 795/902 reads (88%) | called by muse, mutect2, varscan2
- TMEM271 | c.951C>T p.F317= | Silent (SNP) | VAF 32/467 reads (7%) | called by muse, mutect2
- TRIM68 | c.1005A>G p.P335= | Silent (SNP) | VAF 437/587 reads (74%) | called by muse, mutect2, varscan2
- TRIM72 | c.507G>T p.R169= | Silent (SNP) | VAF 129/408 reads (32%) | called by muse, mutect2, varscan2
- TRIO | c.9198G>A p.L3066= | Silent (SNP) | VAF 167/1503 reads (11%) | called by muse, mutect2, varscan2
- TSKU | c.516C>T p.L172= | Silent (SNP) | VAF 206/760 reads (27%) | catalogued as rs764092246; called by muse, mutect2, varscan2
- UBXN2B | c.981C>G p.L327= | Silent (SNP) | VAF 119/246 reads (48%) | called by muse, mutect2, varscan2
- ULBP1 | c.21C>A p.P7= | Silent (SNP) | VAF 120/365 reads (33%) | called by mutect2, varscan2
- UPF1 | c.591C>A p.I197= | Silent (SNP) | VAF 164/634 reads (26%) | called by muse, mutect2, varscan2
- USP6NL | c.1740C>T p.A580= | Silent (SNP) | VAF 151/441 reads (34%) | catalogued as rs769529161; called by muse, mutect2, varscan2
- VCAN | c.8022C>T p.I2674= | Silent (SNP) | VAF 299/400 reads (75%) | called by muse, mutect2, varscan2
- VPS54 | c.1887G>A p.K629= | Silent (SNP) | VAF 47/180 reads (26%) | catalogued as rs770447118; called by muse, mutect2, varscan2
- ZC3H11B | c.2124T>C p.L708= | Silent (SNP) | VAF 86/642 reads (13%) | called by muse, mutect2
- ZNF93 | c.1752G>A p.K584= | Silent (SNP) | VAF 119/461 reads (26%) | catalogued as COSV59374111; called by muse, mutect2, varscan2
- ACVR1B | c.1261+200_1261+202del | Intron (DEL) | VAF 61/336 reads (18%) | called by mutect2, pindel, varscan2
- ATP6AP1L | n.1920G>T | RNA (SNP) | VAF 415/548 reads (76%) | catalogued as COSV101205078, COSV66474677; called by muse, mutect2, varscan2
- C2orf16 | chr2:27574385 G>C | 5'Flank (SNP) | VAF 72/235 reads (31%) | called by muse, mutect2, varscan2
- CCPG1 | c.*3208C>T | 3'UTR (SNP) | VAF 100/393 reads (25%) | catalogued as rs1180425947; called by muse, mutect2, varscan2
- CUL7 | c.-117G>C | 5'UTR (SNP) | VAF 128/357 reads (36%) | called by muse, mutect2, varscan2
- EBLN3P | n.4486T>C | RNA (SNP) | VAF 129/375 reads (34%) | called by muse, mutect2, varscan2
- HMBOX1 | c.1125+323G>C | Intron (SNP) | VAF 90/435 reads (21%) | called by muse, mutect2, varscan2
- ILF3 | chr19:10653497 C>G | 5'Flank (SNP) | VAF 74/316 reads (23%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1393+33186C>T | Intron (SNP) | VAF 306/411 reads (74%) | called by muse, mutect2, varscan2
- LACRT | c.*1G>A | 3'UTR (SNP) | VAF 151/356 reads (42%) | catalogued as rs754628127; called by muse, mutect2, varscan2
- PAMR1 | c.821-10207G>C | Intron (SNP) | VAF 91/398 reads (23%) | called by muse, mutect2, varscan2
- RASSF1 | c.369+601del | Intron (DEL) | VAF 94/421 reads (22%) | called by mutect2, pindel, varscan2
- SEMA5B | c.-38-14734C>T | Intron (SNP) | VAF 108/431 reads (25%) | called by muse, mutect2, varscan2
- UBALD1 | c.120+114G>T | Intron (SNP) | VAF 209/604 reads (35%) | called by muse, mutect2, varscan2
- XPR1 | c.-164A>T | 5'UTR (SNP) | VAF 120/220 reads (55%) | catalogued as rs1355713040; called by muse, mutect2, varscan2
